Surgical pathology report (de-identified scan), TCGA case TCGA-92-7341, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - St. Louis, specimen TCGA-92-7341-01A (Primary Tumor).

[page 1 of 4]
**SURGICAL PATHOLOGY REPORT
FINAL WITH ADDENDUM**

DIAGNOSIS:

LYMPH NODE, LEVEL 7 MEDIASTINUM, EXCISION (FS1)

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

LYMPH NODE, LEVEL 4 MEDIASTINUM, EXCISION (FS2)

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

LYMPH NODE, LEVEL 2R MEDIASTINUM, EXCISION (INCLUDING FS3)

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)
- CASEATING GRANULOMA WITH HYALINIZATION AND CALCIFICATION; AFB AND GMS PENDING
- RESULTS WILL BE ISSUED IN AN ADDENDUM

LYMPH NODES, LEVEL 11 MEDIASTINAL, EXCISION

- NO EVIDENCE OF MALIGNANCY IN FOUR LYMPH NODES (0/4)

LUNG, RIGHT UPPER LOBE, LOBECTOMY (INCLUDING FS4)

- MODERATELY DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA (4.5 CM), WITH TUMORAL NECROSIS
- PLEURA IS FREE OF TUMOR
- ALL SURGICAL MARGINS FREE OF TUMOR
- NO EVIDENCE OF MALIGNANCY IN TWO PERIBRONCHIAL LYMPH NODES (0/2)
- CASEATING GRANULOMA (1.0 CM) WITH HYALINIZATION; GMS AND AFB STAINS PENDING, RESULTS TO BE ISSUED IN AN ADDENDUM
- SEE SYNOPSIS

LYMPH NODE, 10R MEDIASTINUM, EXCISION

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

Intraoperative non-microscopic consultation was obtained and interpreted as: "Brought to frozen is 'right upper lobe' consisting of a 168 gram, 12.5 x 8.0 x 3.5 cm lobe of lung with two masses palpated. The first has an overlying pleural pucker (inked) and is sectioned to show a 4.3 x 3.5 x 3.3 cm lobulated white-gray necrotic mass extending from the main airway (not at the margin) to the pleura. The second mass is entirely intraparenchymal, measuring 1.0 x 0.9 x 0.8 cm, is 2.0 cm from the large mass, and is calcified. The bronchial margin is frozen as FS4. Tissue taken for lung study and tumor bank. Rest for permanents."

FS1: Lymph node, level 7

- "No evidence of malignancy," by

FS2: Lymph node, level 4R, excision

- "No evidence of malignancy"

- No nodal tissue identified," by

FS3: Lymph node, level 2R

- "Calcified portion of submitted lymph node not submitted

- No evidence of malignancy

- No nodal tissue identified," by

FS4: Bronchial margin

- "No evidence of malignancy," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [redacted] with lung cancer (squamous cell carcinoma, [redacted]). Operative procedure: Right upper lobectomy.

Specimen(s) Received:

A: LYMPH NODES, LEVEL 7 MEDIASTINAL
B: LYMPH NODES, LEVEL 4 MEDIASTINAL
C: LYMPH NODES, LEVEL 2R MEDIASTINAL
D: LYMPH NODES, LEVEL 11 MEDIASTINAL
E: LUNG, RIGHT UPPER LOBE
F: LYMPH NODES, 10 R MEDIASTINAL

Gross Description:

The specimens are received in six formalin-filled containers, each labeled [redacted]. The first container is additionally labeled "level 7 - FS1." It holds a cassette labeled "FS1" containing several fragments of fibrofatty and lymphoid tissue measuring 1.5 x 0.5 x 0.4 cm in aggregate. Labeled A1 (FS1). Jar 0.

The second container is labeled "level 4R - FS2" and contains a cassette labeled "FS2" holding a portion of fibrofatty tissue and lymphoid tissue measuring 1.3 x 1.0 x 0.2 cm. Labeled B1 - FS2. Jar 0.

The third container is labeled "level 2R - FS3" and contains a cassette labeled "FS3" containing a portion of adipose tissue measuring 1.6 x 0.5 x 0.1 cm. Also in the container is a calcified nodule measuring 0.7 x 0.3 x 0.3 cm. Acid decalcification. Labeled C1 - FS3; C2 - calcified nodule. Jar 0.

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

The fourth container is labeled "level 11" and it holds a single fragment of lymphoid tissue measuring 2.0 x 2.0 x 0.7 cm. Labeled D. Jar 0.

The fifth container is labeled "right upper lobe - FS4" and it holds a previously sectioned and inked lobe of lung weighing 168 grams and measuring 12.5 x 8.0 x 3.5 cm. The sections show a 4.5 x 4.3 x 3.5 cm multinodular tan, necrotic ill-defined mass extending from the main airway to the overlying pleura. The overlying pleura is inked blue, and the staple line is inked black. Also cut sections show the presence of a second mass measuring 1.0 x 0.9 x 0.8 cm located 2.0 cm from the larger mass and is calcified. The larger mass is 1.5 cm from the nearest stapled margin. The remainder of the lung parenchyma is spongy, brown, and unremarkable. Also in the container is a cassette labeled "FS4" holding bronchial margins and measuring 1.5 x 1.5 x 0.5 cm. Labeled E1 - FS4; E2 - mass with closest overlying pleural surface; E3 - additional section of the tumor; E4 - mass in relation to the bronchial margin; E5 - stapled margin closest the mass; E6 - calcified second mass; E7 - unremarkable lung parenchyma. Jar 3.

The sixth container is labeled "level 10R lymph node" and it holds two fragments of black lymphoid tissue measuring 0.7 x 0.3 x 0.3 cm and 0.3 x 0.2 x 0.2 cm. Labeled F1. Jar 0.

SYNOPTIC REPORTING FORM FOR LUNG CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The histologic classification of the tumor is squamous cell (epidermoid) carcinoma, keratinizing type

HISTOLOGIC GRADE (G)

The grade of the tumor is moderately differentiated (G2)

TUMOR SIZE

The maximum dimension of the tumor is 4.5 cm

LYMPHATIC INVASION

Lymphatic invasion by tumor is absent (L0)

VENOUS INVASION

Venous invasion by tumor is absent (V0)

ARTERIAL INVASION

Arterial invasion by tumor is absent

PLEURAL INVOLVEMENT

Pleural involvement is absent

SAMPLED SPECIMEN MARGINS

The sampled surgical margins are uninvolved by tumor

NON-NEOPLASTIC TISSUE

The non-neoplastic lung tissue shows anthracosis

The non-neoplastic lung tissue shows granulomatous inflammation

PRIMARY TUMOR (T)

Tumor > 3 cm but ≤ 5 cm in greatest dimension (T2a)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis histologically; no examination for ITC (pN0)

The total number of lymph nodes examined is 10

The total number of metastatically-involved lymph nodes is 0

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

DISTANT METASTASIS (M)

Distant metastasis cannot be assessed (MX)

STAGE GROUPING

The overall international stage is pT2a/N0/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Addendum Comment

Numerous yeast forms were identified by GMS stain consistent with Histoplasma species, both in lung and lymph node granuloma sections. AFB stains were negative.

Source: NCI Genomic Data Commons file 75285d64-e5b5-43f6-a74e-38942d9a6862 (TCGA-92-7341.31FC1B19-8A42-4D14-95D1-22E8358D0029.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).